Somatic mutation profile of cancer-model specimen HCM-CSHL-0802-C67-85B (3D Organoid, passage 3; aliquot HCM-CSHL-0802-C67-85B-01D-A88G-36), derived from the primary tumor of HCMI case HCM-CSHL-0802-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; Tumor grade: G3.
Specimen HCM-CSHL-0802-C67-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 3.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47424377-01bb-4bbe-8430-b0be1b9c953e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0802-C67-10A (Blood Derived Normal), aliquot HCM-CSHL-0802-C67-10A-01D-A88G-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29b146b4-8722-4866-93a1-ceea80adab11

The open-access MAF lists 635 somatic variants for this specimen: 418 protein-altering or splice-affecting, 190 silent, 27 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 374, Silent 190, Nonsense Mutation 30, Intron 13, Frame Shift Del 5, 5'Flank 4, 5'UTR 4, 3'UTR 4, Splice Region 3, Frame Shift Ins 2, Splice Site 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MSH6 | c.1993G>T p.E665* | Nonsense Mutation (SNP) | VAF 183/491 reads (37%) | catalogued as rs1333555322, COSV52290439; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 46/140 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121917929, CM066998, CM066999; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 366/367 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TTN | c.47086C>T p.R15696* (on ENST00000591111; = p.R8272* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 46/290 reads (16%) | catalogued as rs1343120755, COSV100624672, COSV59893970; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.131G>C p.R44P | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as COSV99792281; called by muse, mutect2, varscan2
- ADAMTS10 | c.2003C>T p.T668M | Missense Mutation (SNP) | VAF 154/329 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782568976; called by muse, mutect2, varscan2
- ADAMTS12 | c.2810C>G p.S937C | Missense Mutation (SNP) | VAF 150/980 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.248); catalogued as COSV61254513; called by muse, mutect2, varscan2
- ADGRG6 | c.1693A>G p.T565A | Missense Mutation (SNP) | VAF 112/137 reads (82%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs746431638; called by muse, mutect2, varscan2
- ADORA3 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 67/322 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs766923748, COSV53986544; called by muse, mutect2, varscan2
- AHCYL1 | c.1247G>T p.W416L | Missense Mutation (SNP) | VAF 164/404 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); catalogued as COSV100779697; called by muse, mutect2, varscan2
- ALPI | c.773C>A p.A258E | Missense Mutation (SNP) | VAF 113/183 reads (62%) | SIFT tolerated (0.82); PolyPhen benign (0.013); catalogued as rs780997860; called by muse, mutect2, varscan2
- APTX | c.846C>G p.F282L | Missense Mutation (SNP) | VAF 109/147 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779509889; called by muse, mutect2, varscan2
- ARHGAP15 | c.949C>T p.R317* | Nonsense Mutation (SNP) | VAF 74/204 reads (36%) | catalogued as rs763082124, COSV54517013; called by muse, mutect2, varscan2
- ARSG | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 91/165 reads (55%) | SIFT tolerated (0.73); PolyPhen benign (0.084); catalogued as rs570153124, COSV71592939; called by muse, mutect2, varscan2
- ATP6V1G2 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 348/636 reads (55%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.532); catalogued as rs141644284; called by muse, mutect2, varscan2
- BTN3A3 | c.1675C>A p.H559N | Missense Mutation (SNP) | VAF 101/341 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99764877; called by muse, mutect2, varscan2
- BTNL8 | c.1377C>G p.I459M | Missense Mutation (SNP) | VAF 163/239 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99180472; called by muse, mutect2, varscan2
- C4BPA | c.1579G>T p.G527W | Missense Mutation (SNP) | VAF 139/422 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV100891093, COSV65536185; called by muse, mutect2, varscan2
- C5orf34 | c.1069G>T p.G357W | Missense Mutation (SNP) | VAF 68/485 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100175579; called by muse, mutect2, varscan2
- CALR | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 180/340 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV100331220; called by muse, mutect2, varscan2
- CATSPER1 | c.804C>G p.H268Q | Missense Mutation (SNP) | VAF 189/331 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1330304355; called by muse, mutect2, varscan2
- CHST8 | c.1094C>A p.P365Q | Missense Mutation (SNP) | VAF 126/587 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749617284; called by muse, mutect2, varscan2
- CHTF18 | c.2413C>A p.Q805K | Missense Mutation (SNP) | VAF 159/244 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50210206; called by muse, mutect2, varscan2
- COCH | c.1452C>A p.F484L (on ENST00000216361 / NM_001347720.1; = p.F419L on NM_004086.3) | Missense Mutation (SNP) | VAF 134/280 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV53550535; called by mutect2, varscan2
- COL4A4 | c.2762G>C p.G921A | Missense Mutation (SNP) | VAF 139/224 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61634894; called by muse, mutect2, varscan2
- COL7A1 | c.8635C>A p.P2879T | Missense Mutation (SNP) | VAF 79/347 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV56476239; called by muse, mutect2, varscan2
- CPAMD8 | c.2591G>A p.R864H (on ENST00000651564; = p.R817H on NM_015692.5) | Missense Mutation (SNP) | VAF 92/346 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754265681; called by muse, varscan2
- DLGAP2 | c.1525C>T p.R509C | Missense Mutation (SNP) | VAF 282/723 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs747744035, COSV70103813; called by muse, mutect2, varscan2
- DNHD1 | c.37G>C p.D13H | Missense Mutation (SNP) | VAF 76/221 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.258); catalogued as rs145615971; called by muse, mutect2, varscan2
- DOP1B | c.849G>C p.Q283H | Missense Mutation (SNP) | VAF 108/360 reads (30%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.986); catalogued as rs754298902, COSV67695449; called by muse, mutect2, varscan2
- DYNC1H1 | c.9403C>A p.Q3135K | Missense Mutation (SNP) | VAF 138/321 reads (43%) | SIFT tolerated (0.89); PolyPhen benign (0.029); catalogued as rs1049866462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EGFL7 | c.253C>G p.R85G | Missense Mutation (SNP) | VAF 305/443 reads (69%) | SIFT tolerated (0.33); PolyPhen benign (0.277); catalogued as COSV100452072, COSV58247170; called by muse, mutect2, varscan2
- ENPP4 | c.569C>A p.A190E | Missense Mutation (SNP) | VAF 39/241 reads (16%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.614); catalogued as rs1386499550; called by muse, mutect2, varscan2
- EXOSC7 | c.781C>A p.R261S | Missense Mutation (SNP) | VAF 132/274 reads (48%) | SIFT tolerated (0.72); PolyPhen benign (0.012); catalogued as COSV99651931; called by muse, mutect2, varscan2
- FYTTD1 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 102/586 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); catalogued as COSV54083039; called by muse, mutect2, varscan2
- GABRA2 | c.715G>C p.V239L | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.658); catalogued as COSV62916708; called by muse, mutect2
- GFUS | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 85/550 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV99643706; called by muse, mutect2, varscan2
- GNA14 | c.63C>G p.I21M | Missense Mutation (SNP) | VAF 255/404 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs370899063; called by muse, mutect2, varscan2
- GNB1L | c.50G>A p.R17Q | Missense Mutation (SNP) | VAF 222/881 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755525483, COSV61548327; called by muse, mutect2, varscan2
- GNE | c.116G>A p.R39Q (on ENST00000396594 / NM_001128227.3; = p.R8Q on NM_005476.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 167/379 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs763057654, COSV64951324; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPR137 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 148/245 reads (60%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as rs1419767506, COSV100464176; called by muse, mutect2, varscan2
- HES4 | c.35C>T p.S12L | Missense Mutation (SNP) | VAF 229/672 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1202631718, COSV59242824; called by muse, mutect2, varscan2
- HOXD9 | c.683C>A p.A228E | Missense Mutation (SNP) | VAF 158/431 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.066); catalogued as COSV50896251; called by muse, mutect2, varscan2
- IBA57 | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 98/380 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100812773, COSV64510995, COSV64511185; called by muse, mutect2, varscan2
- IFT122 | c.1381G>A p.G461R (on ENST00000348417 / NM_052989.3; = p.G402R on NM_018262.4) | Missense Mutation (SNP) | VAF 155/419 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs368786226; called by muse, mutect2, varscan2
- IRGC | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 374/506 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99746442; called by muse, mutect2, varscan2
- KCNH2 | c.3371C>A p.A1124D | Missense Mutation (SNP) | VAF 196/611 reads (32%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.034); catalogued as COSV51214378; called by muse, varscan2
- KIAA1109 | c.13048C>G p.P4350A | Missense Mutation (SNP) | VAF 182/286 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99152363; called by muse, mutect2, varscan2
- LAMA1 | c.1324C>T p.Q442* | Nonsense Mutation (SNP) | VAF 291/547 reads (53%) | catalogued as COSV101056912; called by muse, mutect2, varscan2
- LAPTM5 | c.411G>A p.M137I | Missense Mutation (SNP) | VAF 64/199 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.346); catalogued as rs1392006173; called by muse, mutect2, varscan2
- LDHC | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 73/109 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.857); catalogued as COSV99772534; called by muse, mutect2, varscan2
- MAN2C1 | c.2796G>C p.L932F | Missense Mutation (SNP) | VAF 104/473 reads (22%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.642); catalogued as COSV51227879; called by muse, mutect2, varscan2
- MBD3L3 | c.445G>T p.V149L | Missense Mutation (SNP) | VAF 143/1787 reads (8%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as rs969280814; called by muse, mutect2
- MGA | c.2840C>G p.S947* | Nonsense Mutation (SNP) | VAF 122/235 reads (52%) | catalogued as COSV54948648; called by muse, mutect2, varscan2
- MKLN1 | c.2005C>G p.H669D | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV61759959; called by muse, mutect2, varscan2
- MMP28 | c.1499G>T p.R500L | Missense Mutation (SNP) | VAF 157/390 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.089); catalogued as rs146307755; called by muse, mutect2, varscan2
- MROH1 | c.501C>A p.S167R | Missense Mutation (SNP) | VAF 215/529 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as COSV58192725; called by muse, mutect2, varscan2
- MST1R | c.2707G>A p.E903K | Missense Mutation (SNP) | VAF 263/526 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs767728277, COSV56572230; called by muse, mutect2, varscan2
- MTNR1B | c.492C>G p.I164M | Missense Mutation (SNP) | VAF 243/411 reads (59%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.515); catalogued as COSV99925345; called by muse, mutect2, varscan2
- MYO1F | c.2990C>A p.A997E | Missense Mutation (SNP) | VAF 167/384 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.044); catalogued as COSV57797643; called by muse, mutect2, varscan2
- NCAM2 | c.2116G>T p.G706C | Missense Mutation (SNP) | VAF 74/144 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs748488774, COSV99520257; called by mutect2, varscan2
- NEK1 | c.1976A>G p.H659R | Missense Mutation (SNP) | VAF 62/134 reads (46%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs944312566; called by muse, mutect2, varscan2
- NF2 | c.863C>G p.S288* | Nonsense Mutation (SNP) | VAF 158/159 reads (99%) | catalogued as COSV58523216; called by muse, mutect2, varscan2
- OR10H3 | c.496C>A p.H166N | Missense Mutation (SNP) | VAF 69/290 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as COSV59944027; called by muse, mutect2, varscan2
- OR6C1 | c.209C>T p.S70L | Missense Mutation (SNP) | VAF 55/203 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.009); catalogued as rs867442232, COSV65572609; called by muse, mutect2, varscan2
- OSMR | c.1775G>T p.R592M | Missense Mutation (SNP) | VAF 48/471 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.766); catalogued as COSV57081646; called by muse, mutect2, varscan2
- OXR1 | c.826G>C p.E276Q (on ENST00000442977 / NM_001198532.1; = p.E275Q on NM_018002.3) | Missense Mutation (SNP) | VAF 86/223 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs1563726061, COSV56328530; called by muse, mutect2, varscan2
- PADI2 | c.828G>T p.M276I | Missense Mutation (SNP) | VAF 104/207 reads (50%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100971046; called by muse, mutect2, varscan2
- PAQR9 | c.912C>A p.F304L | Missense Mutation (SNP) | VAF 139/385 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100503959; called by muse, mutect2, varscan2
- PEG3 | c.3537C>A p.F1179L | Missense Mutation (SNP) | VAF 122/291 reads (42%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.992); catalogued as COSV55634145, COSV99689718; called by muse, mutect2, varscan2
- PHRF1 | c.1597G>T p.A533S (on ENST00000264555 / NM_001286581.2; = p.A532S on NM_020901.4) | Missense Mutation (SNP) | VAF 129/345 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759707741; called by muse, mutect2, varscan2
- PIFO | c.575G>T p.*192Lext*18 | Nonstop Mutation (SNP) | VAF 83/354 reads (23%) | catalogued as COSV63863780; called by muse, mutect2, varscan2
- PLPP4 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 124/193 reads (64%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs748975790, COSV64826844; called by muse, mutect2, varscan2
- PLPPR4 | c.265G>T p.E89* | Nonsense Mutation (SNP) | VAF 83/381 reads (22%) | catalogued as COSV64568536; called by muse, mutect2, varscan2
- PLXND1 | c.5068C>T p.H1690Y | Missense Mutation (SNP) | VAF 526/526 reads (100%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.958); catalogued as COSV60719868; called by muse, mutect2, varscan2
- POLQ | c.6862G>A p.G2288S | Missense Mutation (SNP) | VAF 260/260 reads (100%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs771739818; called by muse, mutect2, varscan2
- POLR2F | c.424G>T p.A142S | Missense Mutation (SNP) | VAF 225/531 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV61005929; called by muse, mutect2, varscan2
- POM121 | c.2081C>T p.S694F (on ENST00000434423; = p.S429F on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 288/613 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.401); catalogued as COSV99989166; called by muse, varscan2
- PTH2R | c.1172G>T p.W391L | Missense Mutation (SNP) | VAF 76/290 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55913938; called by muse, varscan2
- PTK2 | c.2725A>G p.I909V | Missense Mutation (SNP) | VAF 101/270 reads (37%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.926); catalogued as rs1009418037; called by muse, mutect2, varscan2
- PTPRC | c.1118A>G p.Y373C | Missense Mutation (SNP) | VAF 137/189 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs771923388; called by muse, mutect2, varscan2
- PTPRD | c.3968G>A p.R1323H | Missense Mutation (SNP) | VAF 172/256 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as rs1172700321; called by muse, mutect2, varscan2
- PTPRS | c.5756G>C p.R1919P | Missense Mutation (SNP) | VAF 81/376 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53634020; called by muse, mutect2, varscan2
- QRFPR | c.772G>T p.G258* | Nonsense Mutation (SNP) | VAF 93/131 reads (71%) | catalogued as COSV57676811; called by muse, mutect2, varscan2
- RAD17 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV99281430; called by mutect2, varscan2
- RASEF | c.1174C>G p.H392D | Missense Mutation (SNP) | VAF 89/89 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.072); catalogued as rs769817954; called by muse, mutect2, varscan2
- RNF121 | c.784G>T p.G262C | Missense Mutation (SNP) | VAF 82/229 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99474923; called by muse, mutect2, varscan2
- RNF26 | c.1001G>T p.R334I | Missense Mutation (SNP) | VAF 197/337 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV104410200; called by muse, mutect2, varscan2
- ROBO2 | c.2104C>A p.L702M | Missense Mutation (SNP) | VAF 55/419 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59900963; called by muse, mutect2, varscan2
- RYR2 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 385/469 reads (82%) | SIFT tolerated (0.83); PolyPhen possibly damaging (0.833); catalogued as rs1023176208, COSV63718941; called by muse, mutect2, varscan2
- SEC24D | c.1977C>A p.Y659* | Nonsense Mutation (SNP) | VAF 37/128 reads (29%) | catalogued as COSV54876512; called by muse, mutect2, varscan2
- SMYD1 | c.847C>A p.L283M | Missense Mutation (SNP) | VAF 361/363 reads (99%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as COSV70224851; called by muse, mutect2, varscan2
- SOGA1 | c.1216G>T p.A406S | Missense Mutation (SNP) | VAF 101/566 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.502); catalogued as rs747200639; called by muse, mutect2, varscan2
- SOX14 | c.194G>T p.R65L | Missense Mutation (SNP) | VAF 175/487 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1004449220; called by muse, mutect2, varscan2
- SOX17 | c.1001C>A p.S334* | Nonsense Mutation (SNP) | VAF 366/882 reads (41%) | catalogued as COSV52024098; called by muse, varscan2
- SPG7 | c.1527C>A p.F509L (on ENST00000268704; = p.F516L on NM_003119.4) | Missense Mutation (SNP) | VAF 105/173 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV99245635; called by muse, mutect2, varscan2
- SPRN | c.11C>A p.A4E | Missense Mutation (SNP) | VAF 112/184 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as rs763048225; called by muse, mutect2, varscan2
- STOM | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 184/267 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763192503; called by muse, mutect2, varscan2
- TBC1D8 | c.1468G>A p.V490M | Missense Mutation (SNP) | VAF 231/539 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.791); catalogued as rs768495351; called by muse, mutect2, varscan2
- TEK | c.1444C>G p.L482V | Missense Mutation (SNP) | VAF 64/327 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.12); catalogued as rs1275357194; called by muse, mutect2, varscan2
- TSPAN7 | c.323C>A p.S108* | Nonsense Mutation (SNP) | VAF 118/248 reads (48%) | catalogued as COSV54534402; called by muse, mutect2, varscan2
- UBR4 | c.11756C>A p.A3919E | Missense Mutation (SNP) | VAF 178/298 reads (60%) | SIFT tolerated (0.63); PolyPhen benign (0.105); catalogued as COSV64392932; called by muse, mutect2, varscan2
- UNC80 | c.836C>A p.S279Y | Missense Mutation (SNP) | VAF 60/224 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs1225594380; called by muse, varscan2
- USP5 | c.2344G>A p.D782N (on ENST00000229268 / NM_001098536.2; = p.D759N on NM_003481.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/478 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.146); catalogued as rs1176435678; called by muse, mutect2
- WSB2 | c.818G>A p.R273K | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs532558348; called by muse, mutect2, varscan2
- WWC2 | c.2948G>A p.R983H | Missense Mutation (SNP) | VAF 127/209 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs748036038, COSV67858453; called by muse, mutect2, varscan2
- ZNF219 | c.1384C>A p.H462N | Missense Mutation (SNP) | VAF 220/492 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1052466086; called by muse, mutect2, varscan2
- ZNF337 | c.1903C>T p.R635* | Nonsense Mutation (SNP) | VAF 67/529 reads (13%) | catalogued as rs202001008; called by muse, mutect2, varscan2
- ZNF683 | c.790G>T p.G264C | Missense Mutation (SNP) | VAF 116/298 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.125); catalogued as COSV62874738; called by muse, mutect2, varscan2
- AANAT | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 103/320 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- ABCD3 | c.1900G>C p.E634Q | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ABHD1 | c.41C>A p.A14E | Missense Mutation (SNP) | VAF 141/399 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.713G>A p.G238D | Missense Mutation (SNP) | VAF 187/356 reads (53%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AC007998.2 | c.235C>A p.Q79K | Missense Mutation (SNP) | VAF 138/606 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- ACAD11 | c.2305C>A p.L769M | Missense Mutation (SNP) | VAF 155/361 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ACAP2 | c.295G>T p.D99Y | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACO1 | c.517G>T p.G173C | Missense Mutation (SNP) | VAF 71/315 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ACSM4 | c.1222G>T p.G408C | Missense Mutation (SNP) | VAF 99/199 reads (50%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- ADAM32 | c.1126G>T p.V376F | Missense Mutation (SNP) | VAF 50/345 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ADAM33 | c.320C>G p.A107G | Missense Mutation (SNP) | VAF 102/817 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- ADAMTSL4 | c.2218G>T p.G740C | Missense Mutation (SNP) | VAF 251/685 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADCY7 | c.1313G>T p.R438L | Missense Mutation (SNP) | VAF 101/323 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANKFY1 | c.3265C>A p.Q1089K (on ENST00000341657 / NM_001330063.2; = p.Q1090K on NM_016376.5) | Missense Mutation (SNP) | VAF 106/264 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- ANKIB1 | c.2363C>A p.P788Q | Missense Mutation (SNP) | VAF 113/367 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- AP002748.5 | c.1565C>A p.P522Q | Missense Mutation (SNP) | VAF 204/364 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APOC3 | c.28G>T p.A10S | Missense Mutation (SNP) | VAF 185/494 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- APOL1 | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 167/671 reads (25%) | called by muse, mutect2, varscan2
- ARHGAP23 | c.698C>A p.P233Q | Missense Mutation (SNP) | VAF 320/4716 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.043); called by muse, mutect2
- ARHGAP23 | c.1426del p.R476Gfs*16 | Frame Shift Del (DEL) | VAF 3681/5211 reads (71%) | called by mutect2, pindel, varscan2
- ARHGAP32 | c.3797C>G p.T1266S (on ENST00000310343 / NM_001378025.1; = p.T917S on NM_014715.4) | Missense Mutation (SNP) | VAF 110/252 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ARSL | c.1184G>T p.W395L | Missense Mutation (SNP) | VAF 199/571 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ARVCF | c.193C>A p.Q65K | Missense Mutation (SNP) | VAF 164/362 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ATP11A | c.454G>C p.V152L | Missense Mutation (SNP) | VAF 151/449 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- ATP1A3 | c.2535C>A p.D845E (on ENST00000545399 / NM_001256214.2; = p.D832E on NM_152296.5) | Missense Mutation (SNP) | VAF 80/362 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- ATP8B3 | c.2551C>A p.Q851K | Missense Mutation (SNP) | VAF 113/561 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ATRIP | c.1933dup p.R645Kfs*21 (on ENST00000320211 / NM_130384.3; = p.R645Kfs*78 on NM_032166.4) | Frame Shift Ins (INS) | VAF 165/420 reads (39%) | called by mutect2, pindel, varscan2
- ATRNL1 | c.716G>T p.W239L | Missense Mutation (SNP) | VAF 80/248 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ATXN2 | c.1811C>T p.S604F (on ENST00000550104; = p.S444F on NM_002973.4) | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- BAHCC1 | c.3847C>A p.H1283N | Missense Mutation (SNP) | VAF 282/461 reads (61%) | SIFT tolerated (0.23); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- BAHCC1 | c.5426C>A p.P1809Q | Missense Mutation (SNP) | VAF 159/244 reads (65%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- BARHL2 | c.1000G>T p.A334S | Missense Mutation (SNP) | VAF 141/548 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); called by mutect2, varscan2
- BCAM | c.1582C>A p.H528N | Missense Mutation (SNP) | VAF 213/429 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- BMX | c.527C>A p.A176E | Missense Mutation (SNP) | VAF 137/237 reads (58%) | SIFT tolerated (0.96); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- BNIP5 | c.103C>A p.H35N | Missense Mutation (SNP) | VAF 110/458 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- C16orf91 | c.109C>A p.H37N | Missense Mutation (SNP) | VAF 138/419 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- C17orf75 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 45/334 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- C19orf47 | c.4G>T p.V2F | Missense Mutation (SNP) | VAF 76/345 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- C2orf16 | c.2779G>T p.G927* | Nonsense Mutation (SNP) | VAF 126/296 reads (43%) | called by muse, mutect2, varscan2
- C5 | c.3445G>T p.V1149L | Missense Mutation (SNP) | VAF 56/175 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C6orf226 | c.67C>A p.Q23K | Missense Mutation (SNP) | VAF 201/398 reads (51%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- CACNA1E | c.3874A>G p.I1292V | Missense Mutation (SNP) | VAF 99/541 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- CAVIN2 | c.442C>A p.Q148K | Missense Mutation (SNP) | VAF 70/384 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- CC2D2B | c.505G>T p.G169* | Nonsense Mutation (SNP) | VAF 96/97 reads (99%) | called by muse, mutect2, varscan2
- CCDC136 | c.2578C>A p.L860M | Missense Mutation (SNP) | VAF 91/345 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC15 | c.1115C>A p.P372Q | Missense Mutation (SNP) | VAF 176/299 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.421); called by muse, mutect2, varscan2
- CCDC178 | c.727C>A p.Q243K | Missense Mutation (SNP) | VAF 39/258 reads (15%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC191 | c.529A>C p.K177Q | Missense Mutation (SNP) | VAF 61/369 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- CCDC28A | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 20/185 reads (11%) | called by muse, mutect2
- CCDC81 | c.1060C>T p.L354F (on ENST00000445632 / NM_001156474.2; = p.L264F on NM_021827.4) | Missense Mutation (SNP) | VAF 73/146 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- CCDC88B | c.1016G>T p.C339F | Missense Mutation (SNP) | VAF 188/491 reads (38%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCSAP | c.331G>T p.A111S | Missense Mutation (SNP) | VAF 106/713 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CDC42BPG | c.2049C>A p.D683E | Missense Mutation (SNP) | VAF 99/265 reads (37%) | SIFT tolerated (1); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CDCA2 | c.2318C>G p.A773G | Missense Mutation (SNP) | VAF 120/289 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CDH17 | c.2086C>G p.H696D | Missense Mutation (SNP) | VAF 38/293 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDH17 | c.1465T>C p.Y489H | Missense Mutation (SNP) | VAF 166/416 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDIP1 | c.436C>A p.Q146K | Missense Mutation (SNP) | VAF 273/417 reads (65%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- CDK12 | c.4174A>C p.T1392P (on ENST00000447079 / NM_016507.4; = p.T1383P on NM_015083.3) | Missense Mutation (SNP) | VAF 103/3424 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); called by muse, mutect2
- CENATAC | c.421G>T p.E141* | Nonsense Mutation (SNP) | VAF 117/221 reads (53%) | called by muse, mutect2, varscan2
- CFAP99 | c.161G>T p.C54F | Missense Mutation (SNP) | VAF 78/324 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CFAP99 | c.310A>T p.S104C (on ENST00000506607; = p.S589C on NM_001193282.3) | Missense Mutation (SNP) | VAF 124/499 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- CFD | c.488C>A p.P163Q | Missense Mutation (SNP) | VAF 195/758 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, varscan2
- CHDH | c.850C>A p.H284N | Missense Mutation (SNP) | VAF 60/311 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CHGB | c.1297G>T p.D433Y | Missense Mutation (SNP) | VAF 76/698 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- CHMP7 | c.960G>T p.M320I | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- CLDN14 | c.481G>T p.G161C | Missense Mutation (SNP) | VAF 212/591 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CLEC4M | c.1050-1G>T p.X350_splice | Splice Site (SNP) | VAF 39/163 reads (24%) | called by muse, mutect2, varscan2
- CLN6 | c.326C>A p.P109Q | Missense Mutation (SNP) | VAF 105/295 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- CLTC | c.2788C>A p.L930I | Missense Mutation (SNP) | VAF 32/132 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CNTROB | c.1085G>T p.W362L | Missense Mutation (SNP) | VAF 162/298 reads (54%) | SIFT tolerated (0.05); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- COL12A1 | c.1027A>G p.M343V | Missense Mutation (SNP) | VAF 148/181 reads (82%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- CREBRF | c.591G>T p.L197F | Missense Mutation (SNP) | VAF 90/247 reads (36%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- CSMD2 | c.3976C>A p.L1326M | Missense Mutation (SNP) | VAF 164/270 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CYP1B1 | c.1370C>G p.T457S | Missense Mutation (SNP) | VAF 167/427 reads (39%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- CYRIB | c.181C>A p.H61N | Missense Mutation (SNP) | VAF 43/277 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DAGLA | c.1285C>A p.H429N | Missense Mutation (SNP) | VAF 137/242 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DDX59 | c.1755_1759dup p.K587Rfs*49 | Frame Shift Ins (INS) | VAF 196/260 reads (75%) | called by mutect2, varscan2
- DDX59 | c.748G>T p.G250C | Missense Mutation (SNP) | VAF 88/423 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DMRT3 | c.193C>A p.Q65K | Missense Mutation (SNP) | VAF 108/465 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DNAH1 | c.11872G>T p.A3958S | Missense Mutation (SNP) | VAF 85/403 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- DNAH14 | c.1463G>T p.C488F (on ENST00000445597; = p.C469F on NM_001367479.1) | Missense Mutation (SNP) | VAF 31/263 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNM1 | c.1574G>T p.W525L | Missense Mutation (SNP) | VAF 96/159 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DOCK10 | c.2529C>A p.F843L | Missense Mutation (SNP) | VAF 70/143 reads (49%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DOP1B | c.4627G>T p.V1543F | Missense Mutation (SNP) | VAF 177/555 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- DPP6 | c.497G>C p.R166T (on ENST00000377770 / NM_001364500.2; = p.R104T on NM_001936.5) | Missense Mutation (SNP) | VAF 81/287 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DRG2 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 240/241 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- DSP | c.6384G>T p.Q2128H | Missense Mutation (SNP) | VAF 128/309 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DST | c.10829A>C p.D3610A | Missense Mutation (SNP) | VAF 36/231 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- DYRK4 | c.346G>T p.G116* | Nonsense Mutation (SNP) | VAF 164/310 reads (53%) | called by muse, mutect2, varscan2
- EDN3 | c.178G>T p.G60C | Missense Mutation (SNP) | VAF 113/656 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- EIF2B5 | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 125/656 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EIF5B | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- ELAVL3 | c.902G>T p.W301L | Missense Mutation (SNP) | VAF 243/502 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ESRP1 | c.854G>T p.R285M | Missense Mutation (SNP) | VAF 71/373 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EXD2 | c.739G>T p.A247S (on ENST00000312994 / NM_001193362.1; = p.A122S on NM_018199.3) | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAAP20 | c.358C>A p.Q120K | Missense Mutation (SNP) | VAF 268/497 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- FADS1 | c.1474C>A p.Q492K | Missense Mutation (SNP) | VAF 112/219 reads (51%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- FAM171A1 | c.1123G>T p.G375C | Missense Mutation (SNP) | VAF 191/299 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM189B | c.247G>T p.G83C | Missense Mutation (SNP) | VAF 108/832 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXW2 | c.1211C>A p.P404Q | Missense Mutation (SNP) | VAF 106/360 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FER1L5 | c.2090G>T p.W697L (on ENST00000623019; = p.W702L on NM_001293083.2) | Missense Mutation (SNP) | VAF 259/688 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FERMT3 | c.521C>A p.A174E | Missense Mutation (SNP) | VAF 176/320 reads (55%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- FERMT3 | c.1642C>A p.Q548K (on ENST00000279227 / NM_178443.3; = p.Q544K on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 237/428 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- FLG | c.3965C>G p.S1322C | Missense Mutation (SNP) | VAF 99/498 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- FOS | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 225/511 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- FOXI3 | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 153/368 reads (42%) | called by muse, varscan2
- FOXN1 | c.378C>A p.Y126* | Nonsense Mutation (SNP) | VAF 237/383 reads (62%) | called by muse, mutect2, varscan2
- FYCO1 | c.3496G>A p.A1166T | Missense Mutation (SNP) | VAF 213/451 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- GBGT1 | c.898C>A p.H300N | Missense Mutation (SNP) | VAF 224/313 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- GDPD2 | c.568C>G p.L190V | Missense Mutation (SNP) | VAF 277/277 reads (100%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GFPT2 | c.1189G>T p.V397L | Missense Mutation (SNP) | VAF 174/251 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- GFRAL | c.862C>T p.Q288* | Nonsense Mutation (SNP) | VAF 31/218 reads (14%) | called by muse, mutect2, varscan2
- GLCE | c.1765C>A p.L589I | Missense Mutation (SNP) | VAF 136/298 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GOT1 | c.22G>T p.A8S | Missense Mutation (SNP) | VAF 148/235 reads (63%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRHL1 | c.867C>A p.S289R | Missense Mutation (SNP) | VAF 94/237 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- GTF2IRD1 | c.1441G>T p.G481W | Missense Mutation (SNP) | VAF 111/356 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- H3C7 | c.74C>G p.A25G | Missense Mutation (SNP) | VAF 146/299 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HCLS1 | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 289/289 reads (100%) | called by muse, mutect2, varscan2
- HDAC3 | c.604G>T p.G202C | Missense Mutation (SNP) | VAF 99/177 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HINFP | c.886C>G p.L296V | Missense Mutation (SNP) | VAF 145/221 reads (66%) | SIFT tolerated (0.16); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- HM13 | c.355C>A p.H119N | Missense Mutation (SNP) | VAF 239/751 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- HOXA13 | c.889C>A p.Q297K | Missense Mutation (SNP) | VAF 136/460 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- IER5 | c.70C>A p.Q24K | Missense Mutation (SNP) | VAF 102/627 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IFFO1 | c.64C>A p.P22T | Missense Mutation (SNP) | VAF 271/542 reads (50%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.402); called by muse, mutect2, varscan2
- IGLV1-40 | c.283G>C p.A95P | Missense Mutation (SNP) | VAF 308/309 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- INO80B | c.108C>G p.H36Q | Missense Mutation (SNP) | VAF 91/457 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- JPT1 | c.157G>T p.G53W | Missense Mutation (SNP) | VAF 79/289 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KANSL1 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 104/710 reads (15%) | called by muse, mutect2, varscan2
- KAZALD1 | c.245G>T p.C82F | Missense Mutation (SNP) | VAF 318/500 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNF1 | c.168G>T p.L56F | Missense Mutation (SNP) | VAF 142/615 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- KCNQ5 | c.2288C>A p.P763Q | Missense Mutation (SNP) | VAF 198/407 reads (49%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- KIAA1841 | c.1777C>A p.Q593K | Missense Mutation (SNP) | VAF 37/197 reads (19%) | SIFT tolerated (0.75); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- KIFC1 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 130/583 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- KIRREL3 | c.1340C>G p.P447R | Missense Mutation (SNP) | VAF 155/376 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KLF10 | c.1033G>T p.A345S | Missense Mutation (SNP) | VAF 90/443 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- KLHL20 | c.1404_1417del p.D469Sfs*42 | Frame Shift Del (DEL) | VAF 64/587 reads (11%) | called by mutect2, pindel
- KLHL6 | c.1636C>A p.H546N | Missense Mutation (SNP) | VAF 248/587 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KMT2B | c.673G>A p.G225R | Missense Mutation (SNP) | VAF 305/663 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- KMT2E | c.3764C>A p.S1255* | Nonsense Mutation (SNP) | VAF 75/218 reads (34%) | called by muse, mutect2, varscan2
- KRT1 | c.265G>T p.G89C | Missense Mutation (SNP) | VAF 322/510 reads (63%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- LAMB4 | c.4471+1G>C p.X1491_splice | Splice Site (SNP) | VAF 44/125 reads (35%) | called by muse, mutect2, varscan2
- LARS2 | c.*792C>A | Splice Region (SNP) | VAF 48/225 reads (21%) | called by muse, mutect2, varscan2
- LCT | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 385/385 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRG1 | c.949C>A p.Q317K | Missense Mutation (SNP) | VAF 85/372 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0); called by mutect2, varscan2
- LRP2 | c.2723G>A p.G908D | Missense Mutation (SNP) | VAF 86/248 reads (35%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LRP2 | c.2014C>A p.Q672K | Missense Mutation (SNP) | VAF 142/422 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- LRP3 | c.761G>T p.C254F | Missense Mutation (SNP) | VAF 273/563 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- LRP4 | c.2149G>T p.G717C | Missense Mutation (SNP) | VAF 163/278 reads (59%) | SIFT tolerated (0.06); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- LRRC6 | c.307C>G p.L103V | Missense Mutation (SNP) | VAF 84/339 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- LRWD1 | c.1511C>A p.A504E | Missense Mutation (SNP) | VAF 101/333 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- LVRN | c.381C>A p.F127L | Missense Mutation (SNP) | VAF 109/352 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- MAD1L1 | c.143G>T p.S48I | Missense Mutation (SNP) | VAF 110/345 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- MAP3K6 | c.3125G>T p.C1042F | Missense Mutation (SNP) | VAF 242/462 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- MCF2L | c.1681C>A p.Q561K (on ENST00000375608; = p.Q529K on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 339/1448 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- MEGF8 | c.8038C>A p.Q2680K (on ENST00000251268 / NM_001271938.2; = p.Q2613K on NM_001410.3) | Missense Mutation (SNP) | VAF 91/390 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- MIA3 | c.1951C>G p.L651V | Missense Mutation (SNP) | VAF 55/363 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- MLYCD | c.301C>A p.Q101K | Missense Mutation (SNP) | VAF 329/512 reads (64%) | SIFT tolerated (0.98); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MOGS | c.794C>T p.T265I | Missense Mutation (SNP) | VAF 274/275 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- MORC4 | c.1199G>T p.W400L | Missense Mutation (SNP) | VAF 54/110 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- MOV10 | c.1610C>A p.A537E | Missense Mutation (SNP) | VAF 77/291 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- MPI | c.221G>T p.W74L | Missense Mutation (SNP) | VAF 137/317 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- MRPL9 | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 105/368 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- MTUS2 | c.1991C>A p.P664Q | Missense Mutation (SNP) | VAF 198/842 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MUC12 | c.16073C>A p.P5358Q (on ENST00000379442; = p.P5215Q on NM_001164462.1) | Missense Mutation (SNP) | VAF 113/319 reads (35%) | SIFT deleterious (0.01); called by muse, mutect2, varscan2
- MUC16 | c.42361C>T p.P14121S | Missense Mutation (SNP) | VAF 62/285 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MUCL1 | c.127G>T p.D43Y | Missense Mutation (SNP) | VAF 80/259 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- MYH7B | c.53G>T p.C18F | Missense Mutation (SNP) | VAF 51/283 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- MYOCD | c.2449C>A p.L817I | Missense Mutation (SNP) | VAF 152/275 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MYOD1 | c.535T>C p.Y179H | Missense Mutation (SNP) | VAF 229/424 reads (54%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NCL | c.280G>T p.A94S | Missense Mutation (SNP) | VAF 145/271 reads (54%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NDNF | c.311C>A p.S104* | Nonsense Mutation (SNP) | VAF 53/172 reads (31%) | called by muse, mutect2, varscan2
- NDUFS5 | c.298G>T p.G100C | Missense Mutation (SNP) | VAF 64/167 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- NEK10 | c.2075C>A p.T692K | Missense Mutation (SNP) | VAF 49/205 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- NEU4 | c.1042G>T p.G348C (on ENST00000391969 / NM_001167602.3; = p.G360C on NM_080741.4) | Missense Mutation (SNP) | VAF 289/457 reads (63%) | SIFT tolerated (0.27); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- NPDC1 | c.34C>A p.H12N | Missense Mutation (SNP) | VAF 129/421 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- NPHP4 | c.1546C>A p.Q516K | Missense Mutation (SNP) | VAF 242/242 reads (100%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NRIP3 | c.108C>G p.I36M | Missense Mutation (SNP) | VAF 256/449 reads (57%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- OR13C4 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 65/228 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- OR2AP1 | c.125C>A p.T42N | Missense Mutation (SNP) | VAF 83/235 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- OR2M2 | c.282G>T p.M94I | Missense Mutation (SNP) | VAF 74/602 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.017); called by muse, mutect2
- OR4A15 | c.648T>G p.Y216* | Nonsense Mutation (SNP) | VAF 150/247 reads (61%) | called by muse, mutect2, varscan2
- OR4A8 | c.106A>T p.T36S | Missense Mutation (SNP) | VAF 70/235 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.448); called by muse, mutect2, varscan2
- OR4C5 | c.249del p.L84Cfs*7 | Frame Shift Del (DEL) | VAF 75/296 reads (25%) | called by mutect2, pindel, varscan2
- OR4E2 | c.829G>T p.V277L | Missense Mutation (SNP) | VAF 119/281 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR4K5 | c.575C>A p.S192Y | Missense Mutation (SNP) | VAF 46/222 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- OR5M11 | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 83/202 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- OR6Y1 | c.503T>C p.I168T | Missense Mutation (SNP) | VAF 54/404 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OTOL1 | c.1360G>T p.V454F | Missense Mutation (SNP) | VAF 139/390 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- OTUD6A | c.67C>A p.Q23K | Missense Mutation (SNP) | VAF 164/469 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- OXA1L | c.532T>C p.S178P (on ENST00000285848; = p.S118P on NM_005015.5) | Missense Mutation (SNP) | VAF 85/368 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- P2RY2 | c.493C>A p.Q165K | Missense Mutation (SNP) | VAF 374/590 reads (63%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- PAK4 | c.997G>A p.G333S | Missense Mutation (SNP) | VAF 123/601 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PATL2 | c.1618G>T p.A540S | Missense Mutation (SNP) | VAF 69/191 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- PDCD11 | c.5251G>T p.A1751S | Missense Mutation (SNP) | VAF 133/218 reads (61%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.581); called by muse, mutect2, varscan2
- PDCD6IP | c.566T>G p.L189R | Missense Mutation (SNP) | VAF 94/457 reads (21%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- PDHB | c.38G>C p.R13P | Missense Mutation (SNP) | VAF 129/541 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- PELI3 | c.590C>A p.P197Q | Missense Mutation (SNP) | VAF 166/443 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- PEX7 | c.14G>T p.C5F | Missense Mutation (SNP) | VAF 61/377 reads (16%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PGM2 | c.1570G>T p.G524C | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PI4KB | c.1612C>A p.Q538K (on ENST00000368873 / NM_001369623.1; = p.Q550K on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 90/390 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PIEZO2 | c.667G>T p.G223W | Missense Mutation (SNP) | VAF 100/506 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PIK3R6 | c.648C>A p.A216= | Splice Region (SNP) | VAF 149/274 reads (54%) | called by muse, mutect2, varscan2
- PLXDC1 | c.292G>T p.G98C | Missense Mutation (SNP) | VAF 162/3044 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by muse, mutect2
- PLXNC1 | c.4458C>A p.Y1486* | Nonsense Mutation (SNP) | VAF 26/114 reads (23%) | called by mutect2, varscan2
- PMM1 | c.712C>A p.H238N | Missense Mutation (SNP) | VAF 190/363 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); called by muse, mutect2, varscan2
- PNPLA7 | c.2363G>T p.W788L | Missense Mutation (SNP) | VAF 88/282 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- POLR1A | c.2657_2684del p.H886Rfs*2 | Frame Shift Del (DEL) | VAF 75/340 reads (22%) | called by mutect2, pindel, varscan2
- POM121 | c.2820C>A p.F940L (on ENST00000434423; = p.F675L on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 223/557 reads (40%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- POM121L12 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 377/601 reads (63%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- PPP1R13B | c.749T>G p.L250R | Missense Mutation (SNP) | VAF 215/457 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- PPP1R1A | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 305/305 reads (100%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PPP1R7 | c.278G>T p.G93V | Missense Mutation (SNP) | VAF 135/135 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- PPP4R1 | c.2728G>T p.V910L (on ENST00000400556 / NM_001042388.3; = p.V893L on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 148/528 reads (28%) | SIFT tolerated (0.49); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PRKDC | c.1273G>C p.D425H | Missense Mutation (SNP) | VAF 32/200 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTPRS | c.4836G>C p.E1612D | Missense Mutation (SNP) | VAF 190/447 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RAG2 | c.966G>A p.M322I | Missense Mutation (SNP) | VAF 120/220 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- RASA2 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 53/127 reads (42%) | called by muse, mutect2, varscan2
- RASAL2 | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 84/600 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASSF1 | c.262G>C p.D88H (on ENST00000357043 / NM_170714.2; = p.X84_splice on NM_007182.5) | Missense Mutation (SNP) | VAF 85/424 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- RAVER1 | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 187/438 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.075); called by muse, mutect2
- RBSN | c.499G>T p.G167W | Missense Mutation (SNP) | VAF 85/362 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RFC5 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 59/205 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RFT1 | c.552G>T p.L184F | Missense Mutation (SNP) | VAF 56/277 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.187); called by muse, mutect2, varscan2
- RHBDL1 | c.727G>T p.A243S (on ENST00000219551 / NM_001318733.2; = p.A178S on NM_001278720.2) | Missense Mutation (SNP) | VAF 233/360 reads (65%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- RIMBP3 | c.1423C>A p.Q475K | Missense Mutation (SNP) | VAF 150/748 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- RIOK2 | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 145/243 reads (60%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- RNF112 | c.159G>T p.E53D | Missense Mutation (SNP) | VAF 252/477 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- RNF212 | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 146/240 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- RNF31 | c.1276G>T p.G426C | Missense Mutation (SNP) | VAF 264/510 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- RPH3A | c.592G>T p.A198S (on ENST00000389385 / NM_001143854.2; = p.A194S on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 164/240 reads (68%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPN2 | c.1190C>A p.T397K | Missense Mutation (SNP) | VAF 76/421 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RRS1 | c.358C>A p.L120I | Missense Mutation (SNP) | VAF 83/526 reads (16%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- RSAD1 | c.631C>A p.Q211K | Missense Mutation (SNP) | VAF 246/366 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RTBDN | c.538C>G p.H180D (on ENST00000393233 / NM_001270444.1; = p.H212D on NM_031429.2) | Missense Mutation (SNP) | VAF 235/470 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.007); called by muse, varscan2
- RUSC2 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 123/477 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- SCARA3 | c.571C>A p.Q191K | Missense Mutation (SNP) | VAF 70/420 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- SCARF1 | c.2480C>A p.P827Q | Missense Mutation (SNP) | VAF 111/294 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- SCUBE1 | c.1252C>A p.Q418K | Missense Mutation (SNP) | VAF 145/340 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- SCYGR5 | c.104C>G p.S35C | Missense Mutation (SNP) | VAF 395/435 reads (91%) | called by muse, mutect2, varscan2
- SDK2 | c.5619C>G p.I1873M | Missense Mutation (SNP) | VAF 192/194 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- SI | c.865G>T p.G289* | Nonsense Mutation (SNP) | VAF 23/114 reads (20%) | called by muse, mutect2, varscan2
- SIGLEC1 | c.1741C>A p.H581N | Missense Mutation (SNP) | VAF 225/925 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- SIRPD | c.209C>A p.P70Q | Missense Mutation (SNP) | VAF 172/783 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- SIX1 | c.510C>G p.N170K | Missense Mutation (SNP) | VAF 138/310 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC18A1 | c.338C>A p.P113Q | Missense Mutation (SNP) | VAF 47/280 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLC44A3 | c.1855C>A p.L619M (on ENST00000271227 / NM_001114106.3; = p.L571M on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SLC5A7 | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 87/482 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLC9A3 | c.2436C>A p.D812E | Missense Mutation (SNP) | VAF 170/1093 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SMCO2 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 91/189 reads (48%) | SIFT tolerated (0.35); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SMG5 | c.1923C>A p.S641R | Missense Mutation (SNP) | VAF 103/633 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.316); called by muse, mutect2, varscan2
- SNRPA | c.115C>A p.Q39K | Missense Mutation (SNP) | VAF 134/313 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SNRPB2 | c.315del p.E106Kfs*60 | Frame Shift Del (DEL) | VAF 307/537 reads (57%) | called by mutect2, pindel, varscan2
- SOD2 | c.14C>A p.A5E | Missense Mutation (SNP) | VAF 98/365 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SORBS3 | c.914C>G p.A305G | Missense Mutation (SNP) | VAF 47/465 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SORCS1 | c.602G>T p.S201I | Missense Mutation (SNP) | VAF 49/190 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- SOX7 | c.790C>A p.Q264K | Missense Mutation (SNP) | VAF 116/681 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- SPATA5 | c.619C>G p.Q207E | Missense Mutation (SNP) | VAF 68/243 reads (28%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SPC24 | c.34C>A p.Q12K | Missense Mutation (SNP) | VAF 254/511 reads (50%) | SIFT tolerated (0.42); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SRSF11 | c.61G>T p.G21C | Missense Mutation (SNP) | VAF 246/743 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- STAT3 | c.1666G>T p.G556C | Missense Mutation (SNP) | VAF 114/179 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STRIP1 | c.2275G>T p.A759S | Missense Mutation (SNP) | VAF 70/308 reads (23%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- STRN4 | c.1114G>T p.G372C | Missense Mutation (SNP) | VAF 94/452 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- SUZ12 | c.371G>A p.R124K | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- SYBU | c.1846G>T p.A616S (on ENST00000276646 / NM_001099754.2; = p.A615S on NM_017786.6) | Missense Mutation (SNP) | VAF 69/514 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- SYNE1 | c.12792C>A p.A4264= (on ENST00000367255 / NM_182961.4; = p.A4193= on NM_033071.3) | Splice Region (SNP) | VAF 58/108 reads (54%) | called by muse, mutect2, varscan2
- SYNJ1 | c.2930T>G p.M977R | Missense Mutation (SNP) | VAF 82/153 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TAB1 | c.1246C>A p.Q416K | Missense Mutation (SNP) | VAF 227/797 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- TANC2 | c.4196C>A p.P1399Q | Missense Mutation (SNP) | VAF 85/297 reads (29%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- TAS1R3 | c.433C>A p.H145N | Missense Mutation (SNP) | VAF 268/441 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- TBC1D5 | c.2038C>A p.Q680K | Missense Mutation (SNP) | VAF 121/518 reads (23%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TCOF1 | c.2686A>T p.I896F (on ENST00000377797 / NM_001135243.1; = p.I819F on NM_000356.4) | Missense Mutation (SNP) | VAF 188/283 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- TECTA | c.3832C>A p.Q1278K | Missense Mutation (SNP) | VAF 137/323 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- TEX15 | c.4771C>A p.L1591M (on ENST00000256246; = p.L1974M on NM_001350162.2) | Missense Mutation (SNP) | VAF 43/210 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- TIPIN | c.329G>T p.W110L | Missense Mutation (SNP) | VAF 92/211 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- TMCO3 | c.1047G>T p.K349N | Missense Mutation (SNP) | VAF 195/510 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- TMEM86A | c.688C>A p.P230T | Missense Mutation (SNP) | VAF 147/257 reads (57%) | SIFT tolerated (0.18); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- TNRC6A | c.935C>A p.P312Q | Missense Mutation (SNP) | VAF 72/220 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.605); called by muse, mutect2, varscan2
- TOGARAM2 | c.684G>T p.M228I | Missense Mutation (SNP) | VAF 187/530 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TOP2A | c.3662C>A p.P1221Q | Missense Mutation (SNP) | VAF 180/274 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TPRN | c.278G>T p.R93L | Missense Mutation (SNP) | VAF 164/522 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- TRIML2 | c.704G>T p.C235F | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- TSGA10IP | c.830T>C p.I277T | Missense Mutation (SNP) | VAF 123/347 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSKS | c.1022G>T p.W341L | Missense Mutation (SNP) | VAF 107/426 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- TTC30A | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 293/319 reads (92%) | SIFT deleterious (0.02); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- TTC39B | c.910G>T p.G304C | Missense Mutation (SNP) | VAF 85/175 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTC5 | c.770G>T p.W257L | Missense Mutation (SNP) | VAF 176/377 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- TTI1 | c.1567G>T p.A523S | Missense Mutation (SNP) | VAF 177/597 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- TUBD1 | c.127C>G p.Q43E | Missense Mutation (SNP) | VAF 145/224 reads (65%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UACA | c.3376G>T p.G1126C | Missense Mutation (SNP) | VAF 103/209 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- UNKL | c.844C>A p.H282N | Missense Mutation (SNP) | VAF 91/277 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- USP54 | c.4532G>T p.C1511F | Missense Mutation (SNP) | VAF 60/190 reads (32%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- VTN | c.1415G>T p.C472F | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VWC2 | c.97C>A p.L33M | Missense Mutation (SNP) | VAF 198/629 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- WDR26 | c.1045C>A p.R349S (on ENST00000414423 / NM_001379403.1; = p.R249S on NM_025160.7) | Missense Mutation (SNP) | VAF 134/429 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- WDR35 | c.2840C>A p.A947D (on ENST00000345530 / NM_001006657.2; = p.A936D on NM_020779.4) | Missense Mutation (SNP) | VAF 142/142 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZBTB10 | c.493C>A p.L165M | Missense Mutation (SNP) | VAF 281/750 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZBTB22 | c.1324G>T p.G442C | Missense Mutation (SNP) | VAF 86/598 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- ZBTB25 | c.797C>A p.P266Q | Missense Mutation (SNP) | VAF 172/573 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); called by muse, varscan2
- ZFYVE27 | c.766G>T p.G256C | Missense Mutation (SNP) | VAF 94/291 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- ZIC2 | c.191C>A p.P64Q | Missense Mutation (SNP) | VAF 378/1032 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- ZKSCAN4 | c.854G>T p.C285F | Missense Mutation (SNP) | VAF 43/184 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- ZNF114 | c.1001G>T p.C334F | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF30 | c.1040A>G p.K347R | Missense Mutation (SNP) | VAF 260/370 reads (70%) | SIFT deleterious (0.05); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- ZNF416 | c.1345C>A p.Q449K | Missense Mutation (SNP) | VAF 179/391 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- ZNF479 | c.353G>C p.C118S | Missense Mutation (SNP) | VAF 21/262 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2
- ZNF525 | c.415C>G p.Q139E | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- ZNF573 | c.754G>T p.G252W (on ENST00000536220 / NM_001172692.1; = p.G194W on NM_152360.3) | Missense Mutation (SNP) | VAF 64/245 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF730 | c.1188C>A p.Y396* | Nonsense Mutation (SNP) | VAF 39/166 reads (23%) | called by muse, mutect2, varscan2
- ZNFX1 | c.2660G>T p.W887L | Missense Mutation (SNP) | VAF 59/304 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ADAMTS1 | c.492C>A p.A164= | Silent (SNP) | VAF 234/430 reads (54%) | called by muse, mutect2, varscan2
- ADAMTS8 | c.153C>A p.G51= | Silent (SNP) | VAF 242/608 reads (40%) | called by muse, mutect2
- ANGPTL6 | c.432C>G p.L144= | Silent (SNP) | VAF 159/652 reads (24%) | called by muse, mutect2, varscan2
- ANKH | c.747C>A p.A249= | Silent (SNP) | VAF 176/1081 reads (16%) | called by muse, mutect2, varscan2
- AP2A2 | c.1575G>T p.L525= | Silent (SNP) | VAF 178/304 reads (59%) | called by muse, mutect2, varscan2
- APEH | c.93G>T p.L31= | Silent (SNP) | VAF 146/597 reads (24%) | called by muse, mutect2, varscan2
- ARHGEF16 | c.252C>A p.G84= | Silent (SNP) | VAF 143/396 reads (36%) | called by muse, mutect2, varscan2
- ATAD3C | c.900G>T p.L300= | Silent (SNP) | VAF 121/528 reads (23%) | catalogued as rs1295988915; called by muse, mutect2, varscan2
- ATP8B3 | c.1458G>T p.L486= | Silent (SNP) | VAF 130/515 reads (25%) | called by muse, mutect2, varscan2
- ATXN2L | c.1503G>T p.L501= | Silent (SNP) | VAF 115/180 reads (64%) | called by muse, mutect2, varscan2
- B3GALT6 | c.51C>A p.G17= | Silent (SNP) | VAF 247/398 reads (62%) | called by muse, mutect2, varscan2
- BAIAP2 | c.861G>T p.V287= | Silent (SNP) | VAF 83/212 reads (39%) | called by muse, mutect2, varscan2
- BANF2 | c.24G>C p.L8= | Silent (SNP) | VAF 130/412 reads (32%) | called by muse, mutect2, varscan2
- BOD1L1 | c.1068G>A p.Q356= | Silent (SNP) | VAF 90/147 reads (61%) | called by muse, mutect2, varscan2
- C1orf226 | c.180C>A p.A60= | Silent (SNP) | VAF 197/678 reads (29%) | called by muse, mutect2, varscan2
- C4orf46 | c.33G>T p.S11= | Silent (SNP) | VAF 202/322 reads (63%) | called by muse, mutect2, varscan2
- CACNA1A | c.3345C>A p.A1115= | Silent (SNP) | VAF 269/590 reads (46%) | called by muse, mutect2, varscan2
- CACNA1G | c.1551C>A p.A517= | Silent (SNP) | VAF 380/580 reads (66%) | called by muse, mutect2, varscan2
- CACNB1 | c.1563C>T p.D521= | Silent (SNP) | VAF 162/3180 reads (5%) | called by muse, mutect2
- CARD11 | c.1005G>A p.E335= | Silent (SNP) | VAF 260/422 reads (62%) | catalogued as COSV101210757; called by muse, mutect2, varscan2
- CCDC39 | c.2676T>G p.S892= | Silent (SNP) | VAF 185/186 reads (99%) | called by muse, mutect2, varscan2
- CCNL1 | c.729G>A p.E243= | Silent (SNP) | VAF 106/320 reads (33%) | called by muse, mutect2, varscan2
- CD276 | c.414G>T p.V138= | Silent (SNP) | VAF 142/296 reads (48%) | called by muse, mutect2, varscan2
- CDH1 | c.714C>T p.N238= | Silent (SNP) | VAF 144/227 reads (63%) | catalogued as rs780297063, COSV55733828; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDK12 | c.192C>A p.G64= | Silent (SNP) | VAF 157/3835 reads (4%) | called by muse, mutect2
- CDK12 | c.4173C>A p.G1391= (on ENST00000447079 / NM_016507.4; = p.G1382= on NM_015083.3) | Silent (SNP) | VAF 103/3406 reads (3%) | called by muse, mutect2
- CDK5RAP2 | c.5184G>T p.L1728= | Silent (SNP) | VAF 82/331 reads (25%) | called by muse, mutect2, varscan2
- CDKAL1 | c.978C>T p.S326= | Silent (SNP) | VAF 37/340 reads (11%) | catalogued as rs750171067; called by muse, mutect2, varscan2
- CDS2 | c.234C>A p.A78= | Silent (SNP) | VAF 53/480 reads (11%) | catalogued as rs1261883644; called by muse, mutect2, varscan2
- CENPT | c.582C>A p.A194= | Silent (SNP) | VAF 89/282 reads (32%) | called by muse, mutect2, varscan2
- CEP170B | c.4626G>T p.V1542= (on ENST00000453495; = p.V1471= on NM_015005.3) | Silent (SNP) | VAF 258/562 reads (46%) | called by muse, mutect2, varscan2
- CEP250 | c.6555C>A p.A2185= | Silent (SNP) | VAF 171/541 reads (32%) | called by muse, mutect2, varscan2
- CLCN1 | c.957G>T p.L319= | Silent (SNP) | VAF 113/353 reads (32%) | catalogued as rs746212684; called by muse, mutect2, varscan2
- CLUAP1 | c.519C>A p.A173= | Silent (SNP) | VAF 67/125 reads (54%) | called by muse, mutect2, varscan2
- COL13A1 | c.1374G>A p.R458= (on ENST00000398978 / NM_001130103.2; = p.R401= on NM_080798.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 170/171 reads (99%) | catalogued as COSV62574691; called by muse, mutect2, varscan2
- COL28A1 | c.342G>T p.L114= | Silent (SNP) | VAF 92/308 reads (30%) | called by muse, mutect2, varscan2
- COL6A5 | c.1713C>T p.I571= | Silent (SNP) | VAF 52/357 reads (15%) | catalogued as rs1055657133, COSV55217530; called by muse, mutect2, varscan2
- CSF3 | c.441C>A p.A147= | Silent (SNP) | VAF 184/3010 reads (6%) | called by muse, mutect2
- CSMD3 | c.9642T>A p.T3214= (on ENST00000297405 / NM_001363185.1; = p.T3045= on NM_052900.3) | Silent (SNP) | VAF 136/233 reads (58%) | called by muse, mutect2, varscan2
- CUL9 | c.3546C>A p.A1182= | Silent (SNP) | VAF 90/521 reads (17%) | called by muse, mutect2, varscan2
- CXCL3 | c.54G>T p.V18= | Silent (SNP) | VAF 91/381 reads (24%) | called by muse, mutect2, varscan2
- DACH1 | c.1515C>A p.G505= (on ENST00000619232 / NM_001366712.1; = p.G453= on NM_080759.6) | Silent (SNP) | VAF 227/710 reads (32%) | called by muse, varscan2
- DALRD3 | c.1233C>A p.A411= (on ENST00000341949 / NM_001009996.3; = p.A244= on NM_018114.5) | Silent (SNP) | VAF 97/459 reads (21%) | called by muse, mutect2, varscan2
- DAP3 | c.1194C>G p.L398= | Silent (SNP) | VAF 51/470 reads (11%) | catalogued as rs770022270; called by muse, mutect2, varscan2
- DCUN1D4 | c.372C>A p.G124= | Silent (SNP) | VAF 80/130 reads (62%) | catalogued as COSV58120907; called by muse, mutect2, varscan2
- DIDO1 | c.5826C>A p.P1942= | Silent (SNP) | VAF 158/399 reads (40%) | called by muse, mutect2, varscan2
- DNAH5 | c.12645G>C p.A4215= | Silent (SNP) | VAF 46/1068 reads (4%) | catalogued as COSV54247733; called by muse, mutect2
- DNAH5 | c.9468G>T p.V3156= | Silent (SNP) | VAF 140/924 reads (15%) | called by muse, mutect2, varscan2
- DNMT1 | c.3489G>T p.T1163= | Silent (SNP) | VAF 79/287 reads (28%) | catalogued as COSV61580426; called by muse, mutect2, varscan2
- DOT1L | c.498G>T p.V166= | Silent (SNP) | VAF 67/259 reads (26%) | called by muse, mutect2, varscan2
- EGFL8 | c.756G>T p.V252= | Silent (SNP) | VAF 102/646 reads (16%) | called by muse, mutect2, varscan2
- EHMT2 | c.2778G>T p.V926= | Silent (SNP) | VAF 157/308 reads (51%) | called by muse, mutect2, varscan2
- ERVW-1 | c.228C>A p.A76= | Silent (SNP) | VAF 158/474 reads (33%) | called by muse, mutect2, varscan2
- FADS3 | c.1089C>A p.A363= | Silent (SNP) | VAF 139/321 reads (43%) | called by muse, mutect2, varscan2
- FAM102A | c.321G>T p.L107= | Silent (SNP) | VAF 122/175 reads (70%) | called by muse, mutect2, varscan2
- FAM78B | c.129C>A p.R43= | Silent (SNP) | VAF 158/833 reads (19%) | catalogued as COSV57981506; called by muse, mutect2, varscan2
- FBRSL1 | c.546C>A p.L182= | Silent (SNP) | VAF 254/255 reads (100%) | called by muse, mutect2, varscan2
- FGD5 | c.39C>A p.P13= | Silent (SNP) | VAF 177/372 reads (48%) | catalogued as COSV53250311; called by muse, mutect2, varscan2
- FGF19 | c.537C>T p.L179= | Silent (SNP) | VAF 130/374 reads (35%) | called by muse, mutect2, varscan2
- FMO5 | c.1377G>T p.L459= | Silent (SNP) | VAF 91/444 reads (20%) | called by muse, mutect2, varscan2
- FOXJ1 | c.981G>T p.L327= | Silent (SNP) | VAF 264/463 reads (57%) | called by muse, mutect2, varscan2
- GABRR1 | c.258C>T p.F86= | Silent (SNP) | VAF 37/222 reads (17%) | called by muse, mutect2, varscan2
- GAS2L2 | c.231G>T p.L77= | Silent (SNP) | VAF 129/369 reads (35%) | called by muse, mutect2, varscan2
- GBF1 | c.3102C>A p.A1034= (on ENST00000369983 / NM_001377137.1; = p.A1033= on NM_004193.3) | Silent (SNP) | VAF 54/249 reads (22%) | called by muse, mutect2, varscan2
- GBGT1 | c.807G>T p.V269= | Silent (SNP) | VAF 216/300 reads (72%) | called by muse, varscan2
- GJC3 | c.108G>T p.L36= | Silent (SNP) | VAF 243/725 reads (34%) | called by muse, mutect2, varscan2
- GKN3P | c.249C>A p.A83= | Silent (SNP) | VAF 82/436 reads (19%) | called by muse, mutect2, varscan2
- GPC6 | c.1494C>A p.G498= | Silent (SNP) | VAF 211/548 reads (39%) | called by muse, mutect2, varscan2
- GPR179 | c.807G>T p.V269= (on ENST00000621958; = p.V268= on NM_001004334.4) | Silent (SNP) | VAF 160/2222 reads (7%) | called by muse, mutect2
- GRAMD1B | c.180G>T p.L60= | Silent (SNP) | VAF 182/476 reads (38%) | called by muse, mutect2, varscan2
- GRB10 | c.714C>A p.A238= | Silent (SNP) | VAF 77/318 reads (24%) | called by muse, mutect2, varscan2
- GRHL1 | c.912C>T p.I304= | Silent (SNP) | VAF 94/232 reads (41%) | catalogued as rs761844127; called by muse, mutect2, varscan2
- GRM8 | c.1983C>T p.F661= | Silent (SNP) | VAF 147/491 reads (30%) | called by muse, mutect2, varscan2
- HERC2 | c.775A>C p.R259= | Silent (SNP) | VAF 156/362 reads (43%) | called by muse, mutect2, varscan2
- HGF | c.354C>G p.L118= | Silent (SNP) | VAF 48/190 reads (25%) | catalogued as rs769553578, COSV55956239; called by muse, mutect2, varscan2
- HSPA6 | c.1536G>T p.L512= | Silent (SNP) | VAF 143/471 reads (30%) | called by muse, mutect2, varscan2
- HTR1A | c.27C>A p.G9= | Silent (SNP) | VAF 125/195 reads (64%) | catalogued as COSV60501462; called by muse, mutect2, varscan2
- IFNA4 | c.423G>T p.L141= | Silent (SNP) | VAF 91/361 reads (25%) | called by muse, mutect2, varscan2
- ILF2 | c.252G>C p.V84= | Silent (SNP) | VAF 53/330 reads (16%) | called by muse, mutect2, varscan2
- INPP5E | c.792C>A p.R264= | Silent (SNP) | VAF 221/340 reads (65%) | called by muse, mutect2, varscan2
- INPP5E | c.228C>A p.A76= | Silent (SNP) | VAF 336/483 reads (70%) | called by muse, varscan2
- IQCA1L | c.306G>T p.L102= | Silent (SNP) | VAF 219/672 reads (33%) | called by muse, mutect2, varscan2
- KCND1 | c.1584G>A p.L528= | Silent (SNP) | VAF 398/399 reads (100%) | catalogued as rs1557057964, COSV99502080; called by muse, mutect2, varscan2
- KCNK2 | c.621G>T p.V207= (on ENST00000444842 / NM_001017425.3; = p.V192= on NM_014217.4) | Silent (SNP) | VAF 52/324 reads (16%) | called by muse, mutect2, varscan2
- KCNN1 | c.171C>A p.G57= | Silent (SNP) | VAF 123/581 reads (21%) | called by muse, mutect2, varscan2
- KIAA0895L | c.1014C>A p.L338= | Silent (SNP) | VAF 172/492 reads (35%) | called by muse, mutect2, varscan2
- KIAA1522 | c.2214G>T p.V738= (on ENST00000373480 / NM_001198972.2; = p.V797= on NM_020888.3) | Silent (SNP) | VAF 202/338 reads (60%) | called by mutect2, varscan2
- KIF21B | c.4884C>A p.A1628= (on ENST00000422435 / NM_001252100.2; = p.A1615= on NM_017596.4) | Silent (SNP) | VAF 131/709 reads (18%) | catalogued as COSV59762410; called by muse, mutect2, varscan2
- KLHL34 | c.759C>A p.I253= | Silent (SNP) | VAF 536/536 reads (100%) | catalogued as COSV101069940; called by muse, mutect2, varscan2
- KRT84 | c.1125C>A p.R375= | Silent (SNP) | VAF 184/276 reads (67%) | called by muse, mutect2, varscan2
- KRTAP4-8 | c.201C>A p.P67= | Silent (SNP) | VAF 78/188 reads (41%) | catalogued as COSV100417423; called by muse, varscan2
- LAMA5 | c.267G>T p.V89= | Silent (SNP) | VAF 117/585 reads (20%) | called by muse, mutect2, varscan2
- LCORL | c.807G>T p.V269= | Silent (SNP) | VAF 113/161 reads (70%) | called by muse, mutect2, varscan2
- LRRC14B | c.414G>T p.L138= | Silent (SNP) | VAF 257/1518 reads (17%) | called by muse, mutect2, varscan2
- LTN1 | c.4377A>T p.G1459= | Silent (SNP) | VAF 91/199 reads (46%) | called by muse, mutect2, varscan2
- LY75 | c.2523C>A p.A841= | Silent (SNP) | VAF 98/327 reads (30%) | called by muse, mutect2, varscan2
- MAGEB16 | c.882G>T p.V294= | Silent (SNP) | VAF 243/406 reads (60%) | called by muse, mutect2, varscan2
- MALL | c.24C>A p.A8= | Silent (SNP) | VAF 75/559 reads (13%) | called by muse, mutect2, varscan2
- MAPK12 | c.234C>A p.L78= | Silent (SNP) | VAF 152/589 reads (26%) | catalogued as rs1415488299; called by muse, mutect2, varscan2
- MBD3L2 | c.567G>T p.L189= | Silent (SNP) | VAF 180/912 reads (20%) | called by muse, mutect2
- MEGF6 | c.2064G>T p.L688= | Silent (SNP) | VAF 144/379 reads (38%) | called by muse, mutect2, varscan2
- METTL24 | c.42G>T p.L14= | Silent (SNP) | VAF 34/386 reads (9%) | catalogued as rs1390474089; called by muse, mutect2
- MEX3B | c.471G>A p.L157= | Silent (SNP) | VAF 188/446 reads (42%) | called by muse, mutect2, varscan2
- MFHAS1 | c.855C>T p.F285= | Silent (SNP) | VAF 70/453 reads (15%) | catalogued as rs746376157; called by muse, mutect2, varscan2
- MLLT1 | c.1398C>A p.P466= | Silent (SNP) | VAF 56/238 reads (24%) | catalogued as rs1340000320; called by muse, mutect2, varscan2
- MMRN2 | c.2095C>A p.R699= | Silent (SNP) | VAF 305/489 reads (62%) | called by muse, mutect2, varscan2
- MROH2A | c.3534G>T p.L1178= | Silent (SNP) | VAF 73/235 reads (31%) | called by muse, mutect2, varscan2
- MRPS23 | c.300G>T p.V100= | Silent (SNP) | VAF 36/117 reads (31%) | called by muse, mutect2, varscan2
- MRTFA | c.897C>A p.P299= | Silent (SNP) | VAF 157/626 reads (25%) | called by muse, mutect2, varscan2
- MRTFA | c.99C>T p.L33= | Silent (SNP) | VAF 146/570 reads (26%) | called by muse, varscan2
- MUC16 | c.38382G>T p.L12794= | Silent (SNP) | VAF 118/295 reads (40%) | called by muse, mutect2, varscan2
- MUC16 | c.26730C>A p.P8910= | Silent (SNP) | VAF 126/296 reads (43%) | called by muse, mutect2, varscan2
- MUC22 | c.5004G>T p.L1668= | Silent (SNP) | VAF 137/456 reads (30%) | called by muse, mutect2, varscan2
- MYBPC3 | c.3561G>T p.L1187= | Silent (SNP) | VAF 223/374 reads (60%) | called by muse, mutect2, varscan2
- MYH14 | c.1707G>T p.V569= | Silent (SNP) | VAF 201/612 reads (33%) | called by muse, varscan2
- MYO18B | c.2880G>C p.A960= | Silent (SNP) | VAF 169/325 reads (52%) | catalogued as COSV100123203, COSV59137936; called by muse, mutect2, varscan2
- MYO5A | c.3123C>A p.L1041= | Silent (SNP) | VAF 98/199 reads (49%) | catalogued as COSV100697701; called by muse, mutect2, varscan2
- NEMP2 | c.54C>A p.A18= | Silent (SNP) | VAF 110/576 reads (19%) | called by muse, mutect2, varscan2
- NEURL1B | c.369C>A p.V123= | Silent (SNP) | VAF 159/520 reads (31%) | called by muse, mutect2, varscan2
- NID1 | c.3166C>A p.R1056= | Silent (SNP) | VAF 115/651 reads (18%) | called by muse, mutect2, varscan2
- NLGN1 | c.1137C>G p.L379= | Silent (SNP) | VAF 252/253 reads (100%) | catalogued as COSV100849646; called by muse, mutect2, varscan2
- NRROS | c.1221C>T p.F407= | Silent (SNP) | VAF 125/703 reads (18%) | called by muse, mutect2, varscan2
- NYNRIN | c.543G>T p.L181= | Silent (SNP) | VAF 229/489 reads (47%) | catalogued as rs759836430; called by muse, mutect2, varscan2
- ODF3L2 | c.39C>A p.A13= | Silent (SNP) | VAF 101/501 reads (20%) | called by muse, mutect2, varscan2
- OLFM1 | c.975G>A p.L325= (on ENST00000371793 / NM_001282611.2; = p.L307= on NM_014279.5) | Silent (SNP) | VAF 278/279 reads (100%) | catalogued as rs1029475081; called by muse, mutect2, varscan2
- OR2Y1 | c.852C>G p.L284= | Silent (SNP) | VAF 172/172 reads (100%) | catalogued as COSV57136232; called by muse, mutect2, varscan2
- OR9K2 | c.792C>A p.S264= (on ENST00000305377; = p.S242= on NM_001005243.1) | Silent (SNP) | VAF 47/195 reads (24%) | catalogued as COSV59532956; called by muse, mutect2, varscan2
- PCDH11X | c.2913C>T p.T971= | Silent (SNP) | VAF 378/380 reads (99%) | catalogued as COSV100015054; called by muse, mutect2, varscan2
- PCGF2 | c.831C>A p.P277= | Silent (SNP) | VAF 316/4635 reads (7%) | called by muse, mutect2
- PDHA2 | c.171G>A p.A57= | Silent (SNP) | VAF 71/225 reads (32%) | catalogued as rs111350017, COSV54778605, COSV54780565; called by muse, mutect2, varscan2
- PELO | c.1041T>C p.S347= | Silent (SNP) | VAF 86/221 reads (39%) | called by muse, mutect2, varscan2
- PGAP4 | c.57C>T p.S19= | Silent (SNP) | VAF 14/352 reads (4%) | called by muse, mutect2
- PLAAT3 | c.261G>T p.L87= | Silent (SNP) | VAF 252/433 reads (58%) | called by muse, mutect2, varscan2
- PLCH2 | c.489G>T p.L163= | Silent (SNP) | VAF 277/460 reads (60%) | called by muse, mutect2, varscan2
- PLXNA1 | c.3222C>A p.A1074= | Silent (SNP) | VAF 107/614 reads (17%) | called by muse, mutect2, varscan2
- PLXNA4 | c.5049C>A p.A1683= | Silent (SNP) | VAF 90/315 reads (29%) | called by muse, mutect2, varscan2
- PROZ | c.894C>T p.G298= | Silent (SNP) | VAF 353/937 reads (38%) | called by muse, mutect2, varscan2
- RANBP3 | c.33C>A p.A11= | Silent (SNP) | VAF 126/257 reads (49%) | catalogued as COSV50380401; called by mutect2, varscan2
- RANBP6 | c.2601A>G p.P867= | Silent (SNP) | VAF 139/197 reads (71%) | catalogued as rs770135556; called by muse, mutect2, varscan2
- RBBP8NL | c.135C>G p.S45= | Silent (SNP) | VAF 129/370 reads (35%) | catalogued as rs754785012; called by muse, mutect2, varscan2
- RECQL4 | c.3597C>A p.A1199= | Silent (SNP) | VAF 98/611 reads (16%) | called by muse, mutect2, varscan2
- RFXANK | c.693G>T p.V231= | Silent (SNP) | VAF 111/464 reads (24%) | called by muse, mutect2, varscan2
- RGL2 | c.117G>T p.V39= | Silent (SNP) | VAF 217/388 reads (56%) | called by muse, mutect2, varscan2
- RORA | c.135G>T p.V45= | Silent (SNP) | VAF 142/367 reads (39%) | catalogued as rs911354869; called by muse, mutect2, varscan2
- SCN4A | c.531G>T p.L177= | Silent (SNP) | VAF 124/195 reads (64%) | catalogued as COSV71125675; called by muse, mutect2, varscan2
- SHARPIN | c.537G>T p.L179= | Silent (SNP) | VAF 68/492 reads (14%) | called by muse, mutect2, varscan2
- SHARPIN | c.183G>T p.L61= | Silent (SNP) | VAF 158/455 reads (35%) | called by muse, mutect2, varscan2
- SLC16A12 | c.405C>A p.A135= | Silent (SNP) | VAF 140/210 reads (67%) | called by muse, mutect2, varscan2
- SLC1A5 | c.714C>A p.A238= | Silent (SNP) | VAF 262/516 reads (51%) | called by muse, mutect2, varscan2
- SLC1A7 | c.102C>A p.G34= | Silent (SNP) | VAF 106/729 reads (15%) | called by muse, mutect2, varscan2
- SLC22A2 | c.168G>T p.V56= | Silent (SNP) | VAF 124/486 reads (26%) | called by muse, mutect2, varscan2
- SLC25A25 | c.222G>T p.L74= | Silent (SNP) | VAF 240/344 reads (70%) | called by muse, mutect2, varscan2
- SLC26A9 | c.426G>T p.L142= | Silent (SNP) | VAF 85/600 reads (14%) | called by muse, mutect2, varscan2
- SLC35G6 | c.69C>G p.P23= | Silent (SNP) | VAF 236/491 reads (48%) | called by muse, mutect2, varscan2
- SLITRK5 | c.1644T>G p.V548= | Silent (SNP) | VAF 199/546 reads (36%) | called by muse, mutect2, varscan2
- SMIM32 | c.24C>A p.A8= | Silent (SNP) | VAF 99/281 reads (35%) | called by muse, mutect2, varscan2
- SNED1 | c.1434C>A p.G478= | Silent (SNP) | VAF 120/208 reads (58%) | called by muse, mutect2, varscan2
- SNF8 | c.36C>A p.A12= | Silent (SNP) | VAF 146/344 reads (42%) | called by muse, mutect2, varscan2
- SNX21 | c.438C>A p.S146= | Silent (SNP) | VAF 78/339 reads (23%) | called by muse, mutect2, varscan2
- SOGA1 | c.1632G>T p.L544= | Silent (SNP) | VAF 261/816 reads (32%) | called by muse, mutect2, varscan2
- SPOUT1 | c.171G>T p.L57= | Silent (SNP) | VAF 75/266 reads (28%) | called by muse, mutect2, varscan2
- SRBD1 | c.2298C>A p.I766= | Silent (SNP) | VAF 321/324 reads (99%) | called by muse, mutect2, varscan2
- SSTR5 | c.645G>A p.L215= | Silent (SNP) | VAF 436/436 reads (100%) | called by muse, mutect2, varscan2
- SYNE4 | c.501G>C p.R167= | Silent (SNP) | VAF 184/632 reads (29%) | called by muse, mutect2, varscan2
- TACC2 | c.3279G>T p.V1093= | Silent (SNP) | VAF 231/357 reads (65%) | called by muse, mutect2, varscan2
- TAPBPL | c.810G>T p.L270= | Silent (SNP) | VAF 202/401 reads (50%) | called by muse, mutect2, varscan2
- TCAF2 | c.237C>T p.L79= | Silent (SNP) | VAF 60/375 reads (16%) | called by muse, mutect2, varscan2
- TMEM30B | c.147G>T p.L49= | Silent (SNP) | VAF 253/504 reads (50%) | called by muse, mutect2, varscan2
- TMPRSS9 | c.1230G>T p.L410= (on ENST00000648592; = p.L376= on NM_182973.2) | Silent (SNP) | VAF 78/300 reads (26%) | called by muse, mutect2, varscan2
- TNC | c.3432C>T p.I1144= | Silent (SNP) | VAF 229/229 reads (100%) | called by muse, mutect2, varscan2
- TNRC18 | c.5604G>T p.L1868= | Silent (SNP) | VAF 296/780 reads (38%) | called by muse, mutect2, varscan2
- TOPAZ1 | c.4659C>A p.A1553= | Silent (SNP) | VAF 20/112 reads (18%) | called by muse, mutect2, varscan2
- TOR2A | c.168G>T p.L56= | Silent (SNP) | VAF 192/285 reads (67%) | called by muse, mutect2, varscan2
- TPR | c.807C>A p.A269= | Silent (SNP) | VAF 30/250 reads (12%) | called by muse, mutect2, varscan2
- TRO | c.3882C>A p.G1294= | Silent (SNP) | VAF 183/418 reads (44%) | called by muse, mutect2, varscan2
- TUFM | c.1305C>A p.G435= | Silent (SNP) | VAF 73/285 reads (26%) | called by muse, mutect2, varscan2
- UGT2B10 | c.1512A>C p.L504= | Silent (SNP) | VAF 177/274 reads (65%) | called by muse, mutect2, varscan2
- UPF3A | c.579C>A p.A193= | Silent (SNP) | VAF 180/545 reads (33%) | called by muse, mutect2, varscan2
- USH1C | c.129G>T p.V43= | Silent (SNP) | VAF 151/273 reads (55%) | catalogued as COSV99142361; called by muse, mutect2, varscan2
- VAX1 | c.849C>G p.S283= | Silent (SNP) | VAF 136/372 reads (37%) | called by muse, mutect2, varscan2
- VN1R1 | c.720C>A p.G240= | Silent (SNP) | VAF 72/322 reads (22%) | called by muse, mutect2, varscan2
- VPS4A | c.645G>T p.L215= | Silent (SNP) | VAF 68/240 reads (28%) | called by muse, mutect2, varscan2
- VWCE | c.27C>G p.A9= | Silent (SNP) | VAF 180/333 reads (54%) | catalogued as rs1371595158; called by muse, mutect2, varscan2
- WHRN | c.141C>T p.T47= | Silent (SNP) | VAF 274/406 reads (67%) | catalogued as rs968697966; called by muse, mutect2, varscan2
- WIZ | c.3177C>A p.A1059= (on ENST00000673675 / NM_001371589.1; = p.A236= on NM_001330395.4) | Silent (SNP) | VAF 217/504 reads (43%) | called by muse, mutect2, varscan2
- ZBTB7A | c.900G>A p.A300= | Silent (SNP) | VAF 60/650 reads (9%) | called by muse, mutect2
- ZNF532 | c.1362A>G p.P454= | Silent (SNP) | VAF 166/336 reads (49%) | called by muse, mutect2, varscan2
- ZNF648 | c.381C>A p.P127= | Silent (SNP) | VAF 214/690 reads (31%) | catalogued as COSV60570577; called by muse, mutect2, varscan2
- ZNF703 | c.1581C>A p.G527= | Silent (SNP) | VAF 108/677 reads (16%) | catalogued as rs767003255; called by muse, mutect2, varscan2
- ZNF92 | c.1311C>A p.S437= (on ENST00000328747 / NM_152626.4; = p.S368= on NM_007139.4) | Silent (SNP) | VAF 64/224 reads (29%) | called by muse, mutect2, varscan2
- ABI3BP | c.1576+8096C>T | Intron (SNP) | VAF 99/258 reads (38%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73826043 C>T | 5'Flank (SNP) | VAF 87/280 reads (31%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130914939 G>A | 5'Flank (SNP) | VAF 54/299 reads (18%) | called by muse, mutect2, varscan2
- C5orf60 | n.944G>T | RNA (SNP) | VAF 104/186 reads (56%) | called by muse, mutect2, varscan2
- CPNE5 | chr6:36843071 G>C | 5'Flank (SNP) | VAF 120/249 reads (48%) | called by muse, mutect2, varscan2
- EEF1D | c.-7-3134C>A | Intron (SNP) | VAF 133/678 reads (20%) | called by muse, mutect2, varscan2
- FAM219A | c.344+107C>A | Intron (SNP) | VAF 151/318 reads (47%) | called by muse, mutect2, varscan2
- GRIA2 | c.2406+459C>T | Intron (SNP) | VAF 34/127 reads (27%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+16743C>A | Intron (SNP) | VAF 108/176 reads (61%) | called by muse, mutect2, varscan2
- KHDC4 | c.1645+18G>T | Intron (SNP) | VAF 194/625 reads (31%) | called by muse, mutect2, varscan2
- MAP1A | c.-222G>T | 5'UTR (SNP) | VAF 305/305 reads (100%) | called by muse, mutect2, varscan2
- MAP3K14 | c.1553-78C>T | Intron (SNP) | VAF 43/73 reads (59%) | called by muse, mutect2, varscan2
- MIDEAS | c.*338C>A | 3'UTR (SNP) | VAF 220/423 reads (52%) | called by muse, mutect2, varscan2
- MLXIP | c.*49G>T | 3'UTR (SNP) | VAF 148/411 reads (36%) | called by muse, mutect2, varscan2
- NR4A2 | c.-110G>A | 5'UTR (SNP) | VAF 36/253 reads (14%) | called by muse, mutect2, varscan2
- NTMT1 | c.162+81C>A | Intron (SNP) | VAF 110/389 reads (28%) | called by muse, mutect2, varscan2
- PLK5 | c.715-143G>T | Intron (SNP) | VAF 73/457 reads (16%) | called by muse, mutect2, varscan2
- RAF1 | c.-123G>T | 5'UTR (SNP) | VAF 77/349 reads (22%) | called by muse, mutect2, varscan2
- RNF212 | c.246+2909_246+2915del | Intron (DEL) | VAF 79/330 reads (24%) | called by mutect2, pindel, varscan2
- RUFY3 | chr4:70794840 A>T | 3'Flank (SNP) | VAF 53/143 reads (37%) | catalogued as COSV99888169; called by muse, mutect2, varscan2
- SLC38A2 | c.564-46C>A | Intron (SNP) | VAF 101/1009 reads (10%) | called by muse, mutect2
- SNU13 | chr22:41693625 C>A | 5'Flank (SNP) | VAF 185/391 reads (47%) | called by muse, mutect2, varscan2
- STARD3 | c.*35G>C | 3'UTR (SNP) | VAF 248/5512 reads (4%) | called by muse, mutect2
- STARD3 | c.*126C>A | 3'UTR (SNP) | VAF 196/3679 reads (5%) | called by muse, mutect2
- TBX1 | c.1009+496G>T | Intron (SNP) | VAF 195/712 reads (27%) | called by muse, mutect2, varscan2
- VARS2 | c.-423G>T | 5'UTR (SNP) | VAF 61/407 reads (15%) | called by muse, mutect2, varscan2
- YIF1A | c.736-29G>T | Intron (SNP) | VAF 251/464 reads (54%) | called by muse, mutect2, varscan2
